Surgical pathology report (de-identified scan), TCGA case TCGA-SG-A6Z7, project TCGA-SARC (Sarcoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-SG-A6Z7-01A (Primary Tumor).

[page 1 of 3]
Results

Patient Info

Patient Name

Sex

DOB

Component Results

Surgical Pathology Report:

Specimen #: [REDACTED]

Physician:

ICD-0-3

liposarcoma, dedifferentiated 8858/0

Site: Retroperitoneum 248.0

in 12/27/13

FINAL DIAGNOSIS

1. RETROPERINEAL MASS, EXCISION (A) - CONSISTENT DEDIFFERENTIATED LIPOSARCOMA, WITH DIVERGENT DIFFERENTIATION RESEMBLING HIGH-GRADE MALIGNANT PERIPHERAL NERVE SHEATH TUMOR (GRADE 3/3), SEE COMMENT.
2. PERIAORTIC LYMPH NODE #2, DISTAL, EXCISION (B) - NEGATIVE FOR NEOPLASM.
3. PERIAORTIC LYMPH NODE #1, PROXIMAL EXCISION (C) - NEGATIVE FOR NEOPLASM.
4. ABDOMINAL WALL, EXCISION (D) - FIBROADIPOSE TISSUE ASSOCIATED WITH ACUTE INFLAMMATION AND FIBRIN.
- NO EVIDENCE OF NEOPLASM.

COMMENT

1. Although the vast majority of this tumor consists of a high-grade spindle cell sarcoma resembling malignant peripheral nerve sheath tumor, at least focally (slide A11 in particular), there is a lower grade area entirely consistent with a well-differentiated liposarcoma. Taken together, this neoplasm is best classified as a high-grade dedifferentiated liposarcoma. The dedifferentiated area has the morphologic features of a high-grade spindle cell sarcoma resembling a malignant peripheral nerve sheath tumor. Because of the close resemblance to a monophasic synovial sarcoma, paraffin-embedded tissue was analyzed by fluorescent in situ hybridization for the SYT translocation characteristic of synovial sarcoma. However, this alteration was not identified.

Electronic Signature

SPECIMEN SUBMITTED

- A: RETROPERITONEAL TUMOR, R KIDNEY DIAPHRAM AND LIVER
B: PERI AORTIC LYMPH #2 NODE DISTAL
C: PERI AORTIC NODE #1 PROXIMAL
D: ABDOMINAL WALL

CLINICAL DATA

SARCOMA, RETROPERITONEAL

[page 2 of 3]
GROSS DESCRIPTION

A. Received fresh and unoriented is a mass that measures 30.0 x 23.0 x 13.0 cm and weighs 4.0 kg. The majority of the surface is well encapsulated, smooth, shiny and tan-pink. However there is an area present on one aspect that measures 22.0 x 10.0 cm and consists of irregular lobulated hemorrhagic area. The capsule that is present on much of the specimen surface appears to be disrupted in this region. Black ink is applied to the surface and margins are taken in six aspects of the specimen, including the area of capsular disruption. The specimen is serially sectioned revealing an irregular lobulated fleshy tan-white mass with extensive areas of central necrosis and cystic degeneration. Areas of hemorrhage are also present. Present within the specimen is a kidney measuring approximately 11.0 x 6.0 x 4.0 cm. The tumor encases much of the kidney, especially in the hilar region. However the tumor does not appear to invade renal parenchyma. Present approximately 15 cm away is an adrenal measuring 5.0 x 4.0 x 2.0 cm. The tumor has apparently filled the space between the kidney and the adrenal and has completely encased the adrenal. Sectioning reveals a tan-white nodule measuring 2.0 x 1.5 x 1.0 cm and is present within the medulla of the adrenal. The adrenal gland is otherwise unremarkable. Also present is a pink-red irregular segment of tissue possibly representing a portion of liver that measures 7.0 x 6.5 x 4.0 cm. This portion of possible liver also appears to be encased by tumor and definite infiltration of the liver parenchyma is not identified. Gross photograph of the external portion of the specimen and of the cut surface showing relationship between the tumor and the kidney are taken. Fresh tissue is also submitted for frozen archives. Cassettes are submitted in formalin as follows: A1 representative section of tumor at surface with black ink; A2 - A6 representative sections of additional tumor margins with inked capsule; A7 & A8 representative section of kidney with tumor interface; A9 - A18 additional representative sections of tumor, with A11 and A12 showing relationship of tumor with adrenal.

B. Received fresh are two ovoid tan-red firm nodules resembling lymph nodes measuring 1.1 and 2.5 cm in greatest dimension. The nodules are totally submitted in formalin in one cassette.

C. Received fresh are nine ovoid tan-red firm nodules resembling lymph nodes ranging from 0.2 cm to 1.5 cm in greatest dimension. The nodules are totally submitted in formalin in two cassettes: C1 six nodules; C2 three nodules.

D. Received fresh is a polypoid segment of tan-pink soft tissue measuring 2.2 x 1.5 x 0.5 cm. The specimen is not sectioned. Totally submitted in formalin in one cassette.

[REDACTED]
Date of Report:
Date of Procedure
Date of Receipt:
Submitted by:
Location:

Lab and Collection

[REDACTED] on

Lab and Collection Information

[page 3 of 3]
Encounter Date:

Result History

on

Order Result History Report

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Criteria:	W 12/27/13	Yes	No

Source: NCI Genomic Data Commons file 190b58a8-963b-4de7-8682-60e96e0eabc4 (TCGA-SG-A6Z7.617A0548-E893-45C5-BA59-4D9F44A67C08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).